Somatic mutation profile of tumor specimen TCGA-W3-AA21-06A (aliquot TCGA-W3-AA21-06A-11D-A38G-08) from TCGA case TCGA-W3-AA21, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 28.9 years (10,562 days).
Specimen TCGA-W3-AA21-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b28d22c-2457-4982-8d1f-448ccb998304.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W3-AA21-10A (Blood Derived Normal), aliquot TCGA-W3-AA21-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f3a52a0-ccdd-40b9-98e0-057b2c84fdeb

The open-access MAF lists 614 somatic variants for this specimen: 404 protein-altering or splice-affecting, 195 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 362, Silent 195, Nonsense Mutation 29, RNA 7, Intron 5, Splice Region 5, Splice Site 5, Frame Shift Del 2, 5'UTR 2, 3'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/100 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/99 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NPHS2 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786204583, CM042094, CM042096, COSV62635309; ClinVar: likely pathogenic; called by muse, mutect2
- PPP6C | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 29/38 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763733111, COSV65207035; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.3647G>A p.G1216E | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769192036, COSV99792403; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB5 | c.3110C>T p.S1037F (on ENST00000404938 / NM_001163941.2; = p.S592F on NM_178559.6) | Missense Mutation (SNP) | VAF 60/90 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1175097183, COSV51720570; called by muse, mutect2, varscan2
- ABI3BP | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.248); catalogued as COSV52528002, COSV99427266; called by muse, mutect2, varscan2
- AC068580.4 | c.312G>A p.W104* | Nonsense Mutation (SNP) | VAF 22/55 reads (40%) | catalogued as COSV99362430; called by muse, mutect2, varscan2
- ACMSD | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.217); catalogued as rs200534044; called by muse, mutect2, varscan2
- ACSBG2 | c.1750G>A p.G584S | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV99397494; called by muse, mutect2, varscan2
- ADAMTS20 | c.2210T>C p.V737A | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV101166309; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1915C>T p.P639S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99718715, COSV99719550; called by muse, varscan2
- ADAP1 | c.482A>C p.K161T | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99763146; called by muse, mutect2, varscan2
- ADGRB2 | c.4241C>T p.S1414F | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.204); catalogued as COSV99926484; called by muse, mutect2, varscan2
- AHCTF1 | c.6386C>T p.S2129F (on ENST00000366508; = p.S2103F on NM_015446.5) | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs775285144, COSV58257048; called by muse, mutect2, varscan2
- AK9 | c.3475C>T p.R1159C | Missense Mutation (SNP) | VAF 41/52 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767239755, COSV58141801; called by muse, mutect2, varscan2
- AKAP4 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV100654300; called by muse, mutect2, varscan2
- ALCAM | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100065003; called by muse, mutect2, varscan2
- ALDOB | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66397320; called by muse, mutect2, varscan2
- ALPG | c.560G>A p.W187* | Nonsense Mutation (SNP) | VAF 21/60 reads (35%) | catalogued as COSV99779378; called by muse, mutect2, varscan2
- ALPK2 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV64490371; called by muse, mutect2, varscan2
- ANK3 | c.700-1G>A p.X234_splice | Splice Site (SNP) | VAF 9/28 reads (32%) | catalogued as COSV99780601; called by muse, mutect2, varscan2
- ANKRD30A | c.2623G>A p.E875K (on ENST00000611781; = p.E819K on NM_052997.2) | Missense Mutation (SNP) | VAF 83/173 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.692); catalogued as rs1288151210, COSV100653771, COSV100654359; called by muse, mutect2, varscan2
- ANKRD30A | c.3961C>T p.Q1321* (on ENST00000611781; = p.Q1265* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as COSV64604163; called by muse, mutect2, varscan2
- AP1G1 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as COSV100250601; called by muse, mutect2, varscan2
- APCS | c.422G>A p.G141D | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV99661359; called by muse, mutect2, varscan2
- APOA5 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as rs756703832, COSV99911360; called by muse, mutect2, varscan2
- APOL2 | c.176T>C p.L59P | Missense Mutation (SNP) | VAF 74/163 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99969164; called by muse, mutect2, varscan2
- AQP9 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99582996; called by muse, mutect2, varscan2
- ARAP2 | c.2123C>T p.P708L | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100394843; called by muse, mutect2, varscan2
- ARHGAP29 | c.3772C>T p.P1258S | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV53116958; called by muse, mutect2, varscan2
- ARRDC3 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54365742, COSV99475326; called by muse, mutect2, varscan2
- ATCAY | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0.1); catalogued as rs777326805, COSV100008842; called by muse, mutect2, varscan2
- ATP7B | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV54435370, COSV99666591; called by muse, mutect2, varscan2
- AVPR1B | c.605G>A p.W202* | Nonsense Mutation (SNP) | VAF 40/121 reads (33%) | catalogued as COSV100899392; called by muse, mutect2, varscan2
- BBS10 | c.805T>C p.S269P | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV99675211; called by muse, mutect2, varscan2
- BCL9 | c.4126G>A p.G1376S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV99325345; called by muse, mutect2, varscan2
- BMPER | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs751549257, COSV51811410; called by muse, mutect2, varscan2
- BTBD7 | c.2387C>T p.P796L | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV58286598; called by muse, mutect2, varscan2
- BUB1 | c.748T>C p.S250P | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100241365; called by muse, mutect2, varscan2
- C4orf17 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs562665798, COSV100430966; called by muse, mutect2, varscan2
- C7orf61 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs1477288122, COSV100190298; called by muse, mutect2, varscan2
- CACNA1E | c.3236C>T p.P1079L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs745794317, COSV100703373; called by muse, mutect2, varscan2
- CACNA2D3 | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99874566; called by muse, mutect2, varscan2
- CACNA2D4 | c.2281G>A p.G761S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99765886, COSV99766184; called by muse, mutect2
- CALCB | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100158111; called by muse, mutect2, varscan2
- CAPN11 | c.1079T>A p.M360K | Missense Mutation (SNP) | VAF 84/265 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101291900; called by muse, mutect2, varscan2
- CARMIL3 | c.3175C>T p.R1059C | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs774904740, COSV100549663; called by muse, mutect2
- CASP5 | c.645C>A p.D215E | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99507756; called by muse, mutect2, varscan2
- CATSPERB | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV56435218; called by muse, mutect2, varscan2
- CCDC102B | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.11); catalogued as rs199750681; called by muse, mutect2, varscan2
- CCDC3 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); catalogued as COSV101121709; called by muse, mutect2, varscan2
- CCNA1 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217063581, COSV99714665; called by muse, mutect2, varscan2
- CCNL2 | c.1534C>T p.H512Y | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.885); catalogued as COSV101275696; called by muse, mutect2, varscan2
- CCSER2 | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as COSV99826100; called by muse, mutect2, varscan2
- CD163L1 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 84/158 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100550239; called by muse, mutect2, varscan2
- CD1D | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV100939611; called by muse, mutect2, varscan2
- CDH13 | c.785C>T p.T262I | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV99227283; called by muse, mutect2, varscan2
- CEACAM18 | c.379A>G p.T127A | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV101140438; called by muse, mutect2, varscan2
- CEP112 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs767512764, COSV101210820; called by muse, mutect2, varscan2
- CFAP74 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as rs779021655; called by muse, mutect2
- CHAMP1 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.967); catalogued as COSV100778820; called by muse, mutect2, varscan2
- CLCA1 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV99322549; called by muse, mutect2, varscan2
- CLMN | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as rs202217088, COSV54186398; called by muse, mutect2, varscan2
- CMYA5 | c.5042G>A p.G1681E | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV101484149; called by muse, mutect2, varscan2
- CNOT3 | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99652037, COSV99652240; called by muse, mutect2, varscan2
- CNTN1 | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.166); catalogued as rs142561108; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP5 | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 19/64 reads (30%) | catalogued as rs1447158750, COSV70472787; called by muse, mutect2, varscan2
- COCH | c.911G>A p.G304E (on ENST00000216361 / NM_001347720.1; = p.G239E on NM_004086.3) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217792358, COSV53552876; called by muse, mutect2, varscan2
- COL28A1 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as COSV101258721; called by muse, mutect2, varscan2
- COL4A4 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1440886472, COSV100307096; called by muse, mutect2, varscan2
- COLEC12 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101232100; called by muse, mutect2, varscan2
- COLEC12 | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV101232101; called by muse, mutect2, varscan2
- CR1 | c.5366C>T p.P1789L | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.396); catalogued as COSV100887431, COSV100887707; called by muse, mutect2, varscan2
- CRB1 | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs563857130, COSV66328727, COSV66328731; called by muse, mutect2, varscan2
- CSMD2 | c.507C>A p.F169L | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV99591661; called by muse, varscan2
- CSMD2 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs773336805, COSV99591662; called by muse, varscan2
- CSMD3 | c.2971C>T p.R991C (on ENST00000297405 / NM_001363185.1; = p.R887C on NM_052900.3) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1215699658, COSV52182083, COSV52326902, COSV99828366; called by muse, mutect2, varscan2
- CSMD3 | c.1192G>A p.V398I | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.01); catalogued as COSV99837786; called by muse, mutect2, varscan2
- CTAGE1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as COSV101194575; called by muse, mutect2, varscan2
- CTAGE6 | c.702G>A p.W234* | Nonsense Mutation (SNP) | VAF 10/70 reads (14%) | catalogued as rs1360175427, COSV101417860; called by mutect2, varscan2
- CXCR6 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs769108589, COSV99945848; called by muse, mutect2, varscan2
- CYP4F3 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.95); catalogued as rs1449089790, COSV99658296; called by muse, mutect2, varscan2
- DCAF1 | c.2537C>A p.P846H | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV100244560; called by muse, mutect2, varscan2
- DMP1 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV56820739, COSV99218791; called by muse, mutect2, varscan2
- DNAAF5 | c.1712C>T p.T571I | Missense Mutation (SNP) | VAF 51/239 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as COSV99859959; called by muse, mutect2, varscan2
- DNAH11 | c.8065T>A p.F2689I | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100179589; called by muse, mutect2, varscan2
- DNAH12 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1006370903, COSV60855640, COSV60856070; called by muse, mutect2, varscan2
- DNAH5 | c.10912G>A p.E3638K | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs267600359, COSV99451038; called by muse, mutect2, varscan2
- DNAH9 | c.11269C>A p.Q3757K | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99306406; called by muse, mutect2, varscan2
- DNAJC12 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV99830653; called by muse, mutect2, varscan2
- DNAJC5G | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV56080211; called by muse, mutect2, varscan2
- DOK3 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV100467149; called by muse, mutect2, varscan2
- DSCAM | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1306497536, COSV68031023; called by muse, mutect2, varscan2
- DSG3 | c.2036A>G p.K679R | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0.318); catalogued as rs1463737232, COSV99934375; called by muse, mutect2, varscan2
- DSP | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs397516916, COSV101131405; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DST | c.19214C>T p.P6405L (on ENST00000361203 / NM_001374722.1; = p.P4102L on NM_015548.5) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs372733281; called by muse, mutect2, varscan2
- E2F2 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV100674822; called by muse, mutect2, varscan2
- EDEM2 | c.251C>T p.T84I | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100993796; called by muse, mutect2, varscan2
- EFS | c.1646C>T p.A549V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99248879; called by muse, mutect2, varscan2
- EMC7 | c.642G>T p.M214I | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as COSV99854896; called by muse, mutect2, varscan2
- EMILIN3 | c.1429C>T p.L477F | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100182635; called by muse, mutect2, varscan2
- ENAM | c.2599C>T p.H867Y | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as COSV68535845; called by muse, mutect2, varscan2
- EXOG | c.1052T>C p.L351P | Missense Mutation (SNP) | VAF 23/25 reads (92%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.758); catalogued as COSV99815339; called by muse, mutect2, varscan2
- F13B | c.1325G>A p.G442E | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751152638, COSV100803333; called by muse, mutect2, varscan2
- FABP12 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.953); catalogued as rs1361977941, COSV100846579; called by muse, mutect2, varscan2
- FAM83H | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs944312807, COSV101187017; called by muse, mutect2, varscan2
- FANCB | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 46/49 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100146602; called by muse, mutect2, varscan2
- FAT3 | c.2039G>A p.S680N | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV99967305; called by muse, mutect2, varscan2
- FAT3 | c.2212G>A p.D738N | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.024); catalogued as COSV99967309; called by muse, mutect2, varscan2
- FAT4 | c.7546C>T p.H2516Y | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.396); catalogued as rs764574932, COSV58671662; called by muse, mutect2, varscan2
- FAT4 | c.14705G>A p.G4902E | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV100629038; called by muse, mutect2, varscan2
- FBLN5 | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99969695; called by muse, mutect2, varscan2
- FBXO40 | c.1940C>T p.S647F | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100100747; called by muse, mutect2, varscan2
- FBXW12 | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 24/77 reads (31%) | catalogued as rs771925166, COSV99601690; called by muse, mutect2, varscan2
- FCMR | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761700601, COSV65569649; called by muse, mutect2, varscan2
- FCRL4 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0.026); catalogued as COSV99619989; called by muse, mutect2, varscan2
- FCRL6 | c.857G>A p.R286K | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0.006); catalogued as COSV100220244; called by muse, mutect2, varscan2
- FLG | c.5152C>T p.Q1718* | Nonsense Mutation (SNP) | VAF 107/385 reads (28%) | catalogued as COSV100911684, COSV100912394; called by muse, mutect2, varscan2
- FLG | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 131/446 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.155); catalogued as rs149884927, COSV64247011; called by muse, mutect2, varscan2
- FMO2 | c.761G>A p.W254* | Nonsense Mutation (SNP) | VAF 28/96 reads (29%) | catalogued as COSV99269082, COSV99269195; called by muse, mutect2, varscan2
- FMOD | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1271438685, COSV100724565; called by muse, mutect2, varscan2
- FNDC1 | c.5506G>A p.D1836N | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99796113; called by muse, mutect2, varscan2
- FRAS1 | c.4007C>T p.S1336L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs746766578, COSV53625416; called by muse, mutect2, varscan2
- FUBP1 | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV53934486; called by muse, mutect2, varscan2
- FUBP1 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.358); catalogued as COSV99629083; called by muse, mutect2, varscan2
- FXR2 | c.1612C>T p.P538S | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.019); catalogued as rs760603897, COSV100002115, COSV51467361; called by muse, mutect2, varscan2
- GABRA6 | c.1105C>T p.H369Y | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV50878657; called by muse, mutect2, varscan2
- GALNTL5 | c.1192C>T p.R398* | Nonsense Mutation (SNP) | VAF 59/107 reads (55%) | catalogued as rs200861829, COSV67179320; called by muse, mutect2, varscan2
- GEMIN5 | c.2809C>T p.Q937* | Nonsense Mutation (SNP) | VAF 33/72 reads (46%) | catalogued as COSV53564381; called by muse, mutect2, varscan2
- GHR | c.476T>G p.L159* | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | catalogued as CM022016, CM035045, COSV100051124; called by muse, mutect2, varscan2
- GIMAP4 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55431866; called by muse, mutect2, varscan2
- GIPC2 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV100803672; called by muse, mutect2, varscan2
- GM2A | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64095901; called by muse, mutect2, varscan2
- GOLGA5 | c.1768C>T p.R590* | Nonsense Mutation (SNP) | VAF 44/112 reads (39%) | catalogued as rs1248975964, COSV99371034; called by muse, mutect2, varscan2
- GRIFIN | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.472); catalogued as COSV101321756; called by muse, mutect2, varscan2
- GRM2 | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.033); catalogued as COSV99622932; called by muse, mutect2, varscan2
- GRM3 | c.133T>C p.F45L | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100862648; called by muse, mutect2, varscan2
- GRM8 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 72/185 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100283861; called by muse, mutect2, varscan2
- GRXCR2 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.11); catalogued as COSV100939997; called by muse, mutect2, varscan2
- GTSF1L | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 28/99 reads (28%) | catalogued as COSV100883934; called by muse, mutect2, varscan2
- GUCY2C | c.2184G>A p.W728* | Nonsense Mutation (SNP) | VAF 22/59 reads (37%) | catalogued as COSV99663778; called by muse, mutect2, varscan2
- HCK | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52945167; called by muse, mutect2, varscan2
- HCK | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99394163; called by muse, mutect2, varscan2
- HCN1 | c.2476G>A p.G826S | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as COSV100300925; called by muse, mutect2, varscan2
- HCN1 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as COSV57495620, COSV57543783; called by muse, mutect2, varscan2
- HIF3A | c.977G>A p.G326E (on ENST00000377670 / NM_152795.4; = p.G257E on NM_022462.4) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV52204867, COSV99355861; called by muse, mutect2, varscan2
- HIVEP2 | c.5878G>A p.D1960N | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0.198); catalogued as COSV99173934; called by muse, mutect2, varscan2
- HMCN1 | c.6631G>A p.G2211R | Missense Mutation (SNP) | VAF 61/96 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99630905; called by muse, mutect2, varscan2
- HMCN1 | c.6632G>T p.G2211V | Missense Mutation (SNP) | VAF 61/94 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99629207, COSV99630910; called by muse, mutect2, varscan2
- HOXD1 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100514201, COSV58923929; called by muse, mutect2
- HSH2D | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.305); catalogued as rs375693326; called by muse, mutect2, varscan2
- IGFBP6 | c.654G>A p.M218I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.966); catalogued as COSV100037216; called by muse, mutect2, varscan2
- IGHG3 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 95/206 reads (46%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.533); catalogued as rs587597693; called by muse, mutect2, varscan2
- IGLV4-3 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs771704349; called by muse, mutect2, varscan2
- IL18RAP | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV99962134; called by muse, mutect2, varscan2
- IL36A | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99382149; called by muse, mutect2, varscan2
- IL4R | c.1678C>T p.Q560* | Nonsense Mutation (SNP) | VAF 26/53 reads (49%) | catalogued as COSV50162237; called by muse, mutect2, varscan2
- ILF3 | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.158); catalogued as rs1473503487, COSV99139838; called by muse, mutect2, varscan2
- ILK | c.478A>G p.N160D | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100196465; called by muse, mutect2, varscan2
- IMPG1 | c.122G>A p.R41K | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT tolerated (0.5); PolyPhen benign (0.104); catalogued as COSV64056206; called by muse, mutect2, varscan2
- INSM2 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99355184; called by muse, mutect2, varscan2
- ITGB5 | c.1424G>A p.R475K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99950787; called by muse, mutect2, varscan2
- ITIH5 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.149); catalogued as COSV99904968; called by muse, mutect2, varscan2
- ITIH5 | c.1562G>A p.R521K | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.87); PolyPhen benign (0.012); catalogued as COSV99904971; called by muse, mutect2, varscan2
- ITK | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886713435, COSV101439799; called by muse, mutect2, varscan2
- JAK1 | c.2670G>C p.E890D | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as COSV100691966; called by muse, mutect2, varscan2
- JAKMIP2 | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54619043; called by muse, mutect2, varscan2
- KARS1 | c.638T>C p.L213S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100094214; called by muse, mutect2, varscan2
- KAT14 | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV66607581; called by muse, mutect2, varscan2
- KCNB2 | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 56/81 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV73050741; called by muse, mutect2, varscan2
- KCND2 | c.1121G>A p.G374D | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58574817; called by muse, mutect2, varscan2
- KCNJ15 | c.734G>A p.S245N | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (1); PolyPhen probably damaging (0.97); catalogued as COSV60810310; called by muse, mutect2, varscan2
- KCNJ5 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100610721; called by muse, mutect2, varscan2
- KCNN3 | c.1940C>T p.S647F (on ENST00000618040 / NM_001204087.1; = p.S632F on NM_002249.6) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV55228013; called by muse, mutect2, varscan2
- KIF19 | c.1258G>A p.G420R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as rs755794426, COSV100739099; called by muse, varscan2
- KIF1A | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.999); catalogued as rs1237269969, COSV100241423; called by muse, mutect2, varscan2
- KIFC2 | c.1555C>T p.R519W | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs140285981; called by muse, mutect2, varscan2
- KIR3DL1 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.168); catalogued as COSV100428676; called by muse, varscan2
- KIR3DL1 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV58494612; called by muse, mutect2, varscan2
- KLHL23 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.737); catalogued as COSV99775903; called by muse, mutect2, varscan2
- KMT2B | c.3706C>A p.P1236T | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99719901; called by muse, mutect2
- KRT15 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 41/51 reads (80%) | SIFT tolerated (0.43); PolyPhen benign (0.031); catalogued as COSV54181244, COSV99563125; called by muse, mutect2, varscan2
- KRT2 | c.1470G>A p.R490= | Splice Region (SNP) | VAF 26/55 reads (47%) | catalogued as COSV100548529; called by muse, mutect2, varscan2
- KRT26 | c.712G>A p.G238R | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV59412510; called by muse, mutect2, varscan2
- LDB3 | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99555413; called by muse, mutect2, varscan2
- LEPR | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as rs267598693, COSV100756625; called by muse, mutect2, varscan2
- LGI2 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV101180861; called by muse, mutect2, varscan2
- LGSN | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 63/109 reads (58%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.027); catalogued as COSV101040559, COSV65726649; called by muse, mutect2, varscan2
- LILRA4 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.34); catalogued as rs1002404506, COSV52490304, COSV52493488; called by muse, mutect2, varscan2
- LILRB1 | c.191A>G p.K64R (on ENST00000427581; = p.K28R on NM_006669.6) | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.423); catalogued as COSV100207418; called by muse, mutect2, varscan2
- LIPI | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as COSV60711512; called by muse, mutect2, varscan2
- LMAN2 | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as rs747905949, COSV100288416; called by muse, mutect2, varscan2
- LRFN2 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.692); catalogued as rs55706368, COSV100599630; called by muse, mutect2, varscan2
- LRRC49 | c.1611G>A p.M537I | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99537710; called by muse, mutect2, varscan2
- LRTM1 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0.018); catalogued as COSV99836096; called by muse, mutect2, varscan2
- LTN1 | c.4571C>T p.P1524L | Missense Mutation (SNP) | VAF 108/264 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63733457; called by muse, mutect2, varscan2
- LUM | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1396589178, COSV99899087; called by muse, mutect2, varscan2
- LVRN | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV63497454; called by muse, mutect2, varscan2
- MAGEA11 | c.1171C>A p.H391N | Missense Mutation (SNP) | VAF 125/141 reads (89%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100290570; called by muse, mutect2, varscan2
- MAGI2 | c.2893C>T p.R965C | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs370767138, COSV62633071; called by muse, mutect2, varscan2
- MBD1 | c.111C>T p.S37= | Splice Region (SNP) | VAF 6/24 reads (25%) | catalogued as rs1460312558, COSV99496559; called by muse, mutect2
- ME1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as rs1024613609, COSV63838552; called by muse, mutect2, varscan2
- MGA | c.2233C>T p.L745F | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99580410; called by muse, mutect2, varscan2
- MINPP1 | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100916767; called by muse, mutect2, varscan2
- MNDA | c.1127C>G p.T376R | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.075); catalogued as rs200310775, COSV100933361; called by muse, mutect2, varscan2
- MROH7 | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV100273651; called by muse, mutect2, varscan2
- MRPL13 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.875); catalogued as rs745611473, COSV100085506; called by muse, mutect2, varscan2
- MTMR14 | c.1841G>T p.S614I (on ENST00000296003 / NM_001077525.3; = p.S502I on NM_022485.5) | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as rs775835555, COSV99931366; called by muse, mutect2, varscan2
- MUC16 | c.18545G>A p.G6182E | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.053); catalogued as rs866782070, COSV67442014; called by muse, mutect2, varscan2
- MUC16 | c.9896G>A p.G3299E | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.64); catalogued as COSV67491477, COSV67493371; called by muse, mutect2, varscan2
- MUCL3 | c.1543T>C p.S515P (on ENST00000304311; = p.S1391P on NM_080870.4) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV100424211; called by muse, mutect2, varscan2
- N4BP2L2 | c.1613A>G p.Q538R | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV99912611; called by muse, mutect2, varscan2
- NCKAP1L | c.2129G>A p.S710N | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.354); catalogued as COSV99515229; called by muse, mutect2, varscan2
- NDST1 | c.1198C>T p.H400Y | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99938884; called by muse, mutect2, varscan2
- NDST4 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV52113044; called by muse, mutect2, varscan2
- NEK1 | c.2067A>T p.L689F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.193); catalogued as COSV101455710; called by muse, mutect2, varscan2
- NEXMIF | c.2545G>A p.E849K | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as rs777607570, COSV50027401, COSV99279917; ClinVar: likely benign; called by muse, mutect2, varscan2
- NGF | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.94); PolyPhen benign (0.005); catalogued as COSV101049557; called by muse, mutect2, varscan2
- NIN | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs766092666, COSV99813949; called by muse, mutect2, varscan2
- NLRP9 | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 18/84 reads (21%) | catalogued as COSV100243155; called by muse, mutect2, varscan2
- NME8 | c.387+2T>G p.X129_splice | Splice Site (SNP) | VAF 12/61 reads (20%) | catalogued as COSV99553467; called by muse, mutect2, varscan2
- NOS3 | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs933891344, COSV99871816; called by muse, mutect2, varscan2
- NPNT | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as COSV59755408; called by muse, mutect2, varscan2
- NRCAM | c.3775G>A p.G1259R (on ENST00000379028 / NM_001371124.1; = p.G1138R on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 102/239 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61039111; called by muse, mutect2, varscan2
- NRXN3 | c.2440G>A p.E814K (on ENST00000335750 / NM_001330195.2; = p.E441K on NM_004796.6) | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59787117; called by muse, mutect2, varscan2
- NTN5 | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.237); catalogued as COSV99539449; called by muse, mutect2
- NUDT18 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 99/159 reads (62%) | catalogued as rs1226810153, COSV99249080; called by muse, mutect2, varscan2
- OR10W1 | c.864G>A p.M288I | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV67720858; called by muse, mutect2, varscan2
- OR14A16 | c.754G>C p.G252R | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100713804; called by muse, mutect2, varscan2
- OR2A5 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 131/339 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs375899682; called by muse, mutect2, varscan2
- OR2J3 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 166/270 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs762835534, COSV101013561, COSV65848968; called by muse, mutect2, varscan2
- OR2L2 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV100823928; called by muse, mutect2, varscan2
- OR2T12 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100527833; called by muse, mutect2, varscan2
- OR4A5 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.02); catalogued as COSV60522263, COSV60522418; called by muse, mutect2, varscan2
- OR4K15 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs755018034, COSV59301089; called by muse, mutect2, varscan2
- OR51E2 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV101211354, COSV67806929; called by muse, mutect2, varscan2
- OR51M1 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100150133, COSV100150270; called by muse, mutect2, varscan2
- OR5M10 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV101595898; called by muse, mutect2, varscan2
- OR6C65 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV101110192; called by muse, mutect2, varscan2
- OR6C70 | c.10C>T p.H4Y | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV100524440; called by muse, mutect2, varscan2
- OR6C75 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV58553225; called by muse, mutect2, varscan2
- OR6Q1 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs980696204, COSV100110117; called by muse, mutect2
- OR8A1 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.707); catalogued as COSV99420648; called by muse, mutect2, varscan2
- OSBP2 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV100213322; called by muse, mutect2, varscan2
- OSMR | c.1786C>T p.R596* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as rs199844167; called by muse, mutect2, varscan2
- PAOX | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.269); catalogued as rs774849639, COSV99529915; called by muse, mutect2, varscan2
- PARP3 | c.1466G>A p.G489D | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV101290668; called by muse, mutect2, varscan2
- PCDH15 | c.4241G>A p.R1414Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs866920137, COSV57268337; called by muse, mutect2, varscan2
- PCDH18 | c.1424C>T p.S475L | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as COSV100787390; called by muse, mutect2, varscan2
- PCDHB12 | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99507422; called by muse, mutect2, varscan2
- PCDHB16 | c.1148C>T p.S383F | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.812); catalogued as COSV53359701; called by muse, mutect2, varscan2
- PCDHB2 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.034); catalogued as COSV52031000; called by muse, mutect2, varscan2
- PCDHB4 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV52023476, COSV52024717; called by muse, mutect2, varscan2
- PCDHGA1 | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100966002, COSV65295341; called by muse, mutect2, varscan2
- PCK2 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0.144); catalogued as rs747648609, COSV99394468; called by muse, mutect2, varscan2
- PCLO | c.11587G>A p.E3863K | Missense Mutation (SNP) | VAF 163/385 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61621952; called by muse, mutect2, varscan2
- PCLO | c.10621G>A p.A3541T | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as rs573456576, COSV100433919; called by muse, mutect2, varscan2
- PCLO | c.5810G>A p.R1937Q | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as rs750274296, COSV61629961; called by muse, mutect2, varscan2
- PDGFRA | c.3202G>A p.E1068K | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV99956909; called by muse, mutect2, varscan2
- PGBD1 | c.522G>T p.Q174H | Missense Mutation (SNP) | VAF 51/89 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV99460490; called by muse, mutect2, varscan2
- PGBD1 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs998335516, COSV99460494; called by muse, mutect2, varscan2
- PIK3AP1 | c.1800G>A p.M600I | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV100225894; called by muse, mutect2, varscan2
- PKHD1 | c.5887C>T p.L1963F | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100583544; called by muse, mutect2, varscan2
- PKHD1L1 | c.10412C>A p.P3471H | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as COSV101006370; called by muse, mutect2
- PLBD2 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866885404, COSV99785367; called by muse, mutect2, varscan2
- PLCB4 | c.2050G>A p.D684N | Missense Mutation (SNP) | VAF 80/138 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV99595894; called by muse, mutect2, varscan2
- PLEC | c.4307C>T p.P1436L (on ENST00000322810 / NM_201380.4; = p.P1326L on NM_000445.5) | Missense Mutation (SNP) | VAF 44/61 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs201955391, COSV100515588; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXNA4 | c.5614G>A p.D1872N | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as rs772611297, COSV100325042; called by muse, mutect2, varscan2
- POLQ | c.4054G>C p.G1352R | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV99952417; called by muse, mutect2, varscan2
- POM121C | c.730G>C p.V244L (on ENST00000607367; = p.V2L on NM_001099415.3) | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV99992827; called by muse, mutect2, varscan2
- POU6F2 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV68881012; called by muse, mutect2, varscan2
- PPP4R4 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.156); catalogued as COSV58557239; called by muse, mutect2, varscan2
- PPP4R4 | c.1869G>A p.M623I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV58554835; called by muse, mutect2, varscan2
- PRAMEF20 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 118/283 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as rs1234445065; called by muse, mutect2, varscan2
- PRDM4 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV57304808; called by muse, mutect2, varscan2
- PRICKLE1 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100566338, COSV100566473; called by muse, mutect2, varscan2
- PRKD2 | c.1577-1G>A p.X526_splice | Splice Site (SNP) | VAF 5/16 reads (31%) | catalogued as COSV99354385; called by muse, mutect2, varscan2
- PRSS16 | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 34/122 reads (28%) | catalogued as COSV100041801; called by muse, mutect2, varscan2
- PSD3 | c.1066T>A p.L356I | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.1); catalogued as COSV100496535; called by muse, mutect2, varscan2
- PTPRO | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); catalogued as rs771824880, COSV55527005; called by muse, mutect2, varscan2
- PXDNL | c.3793C>T p.Q1265* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV100684428; called by muse, mutect2, varscan2
- PXDNL | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1177849906, COSV62480262; called by muse, mutect2, varscan2
- PYGB | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV99405211; called by muse, mutect2, varscan2
- QSER1 | c.650C>T p.S217L (on ENST00000399302; = p.S346L on NM_001076786.3) | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV101234882; called by muse, mutect2, varscan2
- RAD54L2 | c.4207C>T p.P1403S | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs1234750870, COSV99621493; called by muse, mutect2, varscan2
- RAI1 | c.4894T>C p.S1632P | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as COSV99884323; called by muse, mutect2, varscan2
- RAPGEF3 | c.2374G>A p.D792N (on ENST00000389212; = p.D750N on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99406479; called by muse, mutect2, varscan2
- RASGEF1C | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV100746072; called by muse, mutect2, varscan2
- RBM4 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs1336530720, COSV100029669; called by muse, mutect2, varscan2
- RBM46 | c.1460C>T p.S487F | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as rs141427057; called by muse, mutect2, varscan2
- RBM47 | c.1540C>T p.Q514* (on ENST00000295971 / NM_001098634.2; = p.Q445* on NM_019027.4) | Nonsense Mutation (SNP) | VAF 46/104 reads (44%) | catalogued as COSV99920991; called by muse, mutect2, varscan2
- RET | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV100393893; called by muse, mutect2, varscan2
- RGS6 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.279); catalogued as rs762687373, COSV59566517; called by muse, mutect2, varscan2
- RIBC2 | c.407T>C p.V136A | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100663304; called by muse, mutect2, varscan2
- RIMS2 | c.405T>A p.N135K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101267321; called by muse, mutect2, varscan2
- RP1 | c.3691G>A p.G1231R | Missense Mutation (SNP) | VAF 57/85 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs781423072, COSV99607873; called by muse, mutect2, varscan2
- RP1 | c.3692G>T p.G1231V | Missense Mutation (SNP) | VAF 58/86 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV99607877; called by muse, mutect2, varscan2
- RP1L1 | c.2150G>A p.G717E | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV101223341; called by muse, mutect2, varscan2
- RPS14 | c.150-1G>A p.X50_splice | Splice Site (SNP) | VAF 21/65 reads (32%) | catalogued as rs879098350, COSV100365308; called by muse, mutect2, varscan2
- RTL9 | c.2189G>A p.G730E | Missense Mutation (SNP) | VAF 38/43 reads (88%) | SIFT tolerated (0.19); PolyPhen benign (0.171); catalogued as COSV71825346; called by muse, mutect2, varscan2
- RYR3 | c.10181C>T p.S3394L (on ENST00000389232; = p.S3395L on NM_001036.6) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1442312090, COSV66803668; called by muse, mutect2, varscan2
- S100A8 | c.49C>T p.H17Y | Missense Mutation (SNP) | VAF 70/228 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100907103; called by muse, mutect2, varscan2
- SCOC | c.188C>T p.S63F (on ENST00000608372; = p.S26F on NM_032547.3) | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV100639596; called by muse, mutect2, varscan2
- SDK1 | c.5518G>A p.E1840K | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.903); catalogued as rs760624642, COSV101269526, COSV67389663; called by muse, mutect2, varscan2
- SDK2 | c.5122G>A p.D1708N | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs748296026, COSV101166974; called by muse, mutect2, varscan2
- SDR9C7 | c.242C>T p.T81I | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99524639; called by muse, mutect2, varscan2
- SERPINB11 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66956459; called by muse, mutect2, varscan2
- SERPINI1 | c.1210G>A p.G404R | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.711); catalogued as COSV55508542, COSV99855154; called by muse, mutect2, varscan2
- SF3A1 | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.981); catalogued as COSV99305517; called by muse, mutect2, varscan2
- SH2D3A | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.912); catalogued as rs1187921611, COSV99838052; called by muse, mutect2, varscan2
- SH3RF2 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767712032, COSV63037058; called by muse, mutect2, varscan2
- SHROOM2 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 34/36 reads (94%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.51); catalogued as rs1283200674, COSV66610992, COSV66611557; called by muse, mutect2, varscan2
- SIMC1 | c.1450C>T p.P484S (on ENST00000443967 / NM_001308196.1; = p.P69S on NM_198567.5) | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs749848042, COSV57908384; called by muse, mutect2, varscan2
- SLC12A3 | c.1674G>A p.W558* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99344360; called by muse, mutect2
- SLC15A2 | c.1140G>A p.M380I | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.557); catalogued as COSV99815597; called by muse, mutect2, varscan2
- SLC17A4 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 91/162 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100930623; called by muse, mutect2, varscan2
- SLC24A1 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs760771112, COSV99978365; called by muse, mutect2, varscan2
- SLC35F3 | c.233C>T p.S78F (on ENST00000366617 / NM_001300845.1; = p.S147F on NM_173508.4) | Missense Mutation (SNP) | VAF 75/247 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.186); catalogued as COSV64019600; called by muse, mutect2, varscan2
- SLC5A11 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.801); catalogued as rs986808879, COSV61741630; called by muse, mutect2, varscan2
- SLC5A11 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV61740137, COSV61744012; called by muse, mutect2, varscan2
- SLC9C2 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100876815; called by muse, mutect2, varscan2
- SLC9C2 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.011); catalogued as rs768879119, COSV100876818; called by muse, mutect2, varscan2
- SLCO1B3 | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV53938723; called by muse, mutect2, varscan2
- SLITRK4 | c.2260G>A p.D754N | Missense Mutation (SNP) | VAF 74/82 reads (90%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as COSV100567391; called by muse, mutect2, varscan2
- SNX24 | c.388C>T p.H130Y | Missense Mutation (SNP) | VAF 76/129 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99756916; called by muse, mutect2, varscan2
- SNX31 | c.1199G>A p.S400N | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.212); catalogued as COSV100310221; called by muse, mutect2, varscan2
- SORCS3 | c.3550G>A p.D1184N | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV100865313; called by muse, mutect2, varscan2
- SPAG6 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV100510347; called by muse, mutect2, varscan2
- SPATA2 | c.864G>T p.K288N | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV99192869; called by muse, mutect2, varscan2
- SPEG | c.9609C>T p.P3203= | Splice Region (SNP) | VAF 20/41 reads (49%) | catalogued as COSV100404822; called by muse, mutect2, varscan2
- SPG11 | c.2213T>A p.I738K | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs886685209, COSV99968960; called by muse, mutect2, varscan2
- SRP72 | c.1315C>T p.H439Y | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.178); catalogued as COSV100714323; called by muse, mutect2, varscan2
- STARD13 | c.601G>A p.E201K (on ENST00000336934 / NM_001243476.3; = p.E83K on NM_052851.3) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.266); catalogued as rs754717008, COSV55227579; called by muse, mutect2, varscan2
- STAT4 | c.84G>A p.M28I | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100636088; called by muse, mutect2, varscan2
- STYXL2 | c.3361C>T p.R1121W | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs759325412, COSV54802248; called by muse, mutect2, varscan2
- STYXL2 | c.3464G>A p.R1155K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as COSV99609428; called by muse, mutect2, varscan2
- SUSD4 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.896); catalogued as COSV100663800; called by muse, mutect2, varscan2
- SV2B | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs761763850, COSV57699424; called by muse, mutect2, varscan2
- SVIL | c.2185C>T p.R729C (on ENST00000355867 / NM_021738.3; = p.R335C on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs536836258, COSV63445215; called by muse, mutect2, varscan2
- SYT10 | c.1193C>T p.S398L | Missense Mutation (SNP) | VAF 63/110 reads (57%) | SIFT tolerated (0.64); PolyPhen benign (0.04); catalogued as COSV99951559; called by muse, mutect2, varscan2
- SYT10 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as rs1466482159, COSV57343627; called by muse, mutect2, varscan2
- SYT6 | c.1402G>A p.G468R (on ENST00000610222 / NM_001366225.1; = p.G383R on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65775263; called by muse, mutect2
- TACC2 | c.1013G>A p.G338E | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV100552666; called by muse, mutect2, varscan2
- TBC1D5 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.013); catalogued as COSV99511039; called by muse, mutect2, varscan2
- TCIRG1 | c.1164C>T p.P388= | Splice Region (SNP) | VAF 18/58 reads (31%) | catalogued as rs142053937; called by muse, mutect2, varscan2
- TECTA | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.027); catalogued as COSV50691083; called by muse, mutect2, varscan2
- TENM1 | c.3661C>T p.P1221S | Missense Mutation (SNP) | VAF 68/78 reads (87%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs868670043, COSV64449169; called by muse, mutect2, varscan2
- TENM1 | c.1139G>A p.G380E | Missense Mutation (SNP) | VAF 55/68 reads (81%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as rs867955336, COSV64432419; called by muse, mutect2, varscan2
- TG | c.8230G>A p.E2744K | Missense Mutation (SNP) | VAF 45/66 reads (68%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as COSV55075444; called by muse, mutect2, varscan2
- TGM5 | c.1403G>T p.S468I (on ENST00000220420 / NM_201631.4; = p.S386I on NM_004245.4) | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as COSV55012404; called by muse, mutect2, varscan2
- THOC2 | c.1786C>T p.P596S | Missense Mutation (SNP) | VAF 75/82 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99833604; called by muse, mutect2, varscan2
- THSD4 | c.10C>T p.H4Y | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV99965937, COSV99966071; called by muse, mutect2, varscan2
- THSD7B | c.2600C>T p.P867L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99746981, COSV99750337; called by muse, mutect2, varscan2
- THSD7B | c.3538G>A p.E1180K (on ENST00000272643; = p.E1178K on NM_001316349.2) | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.699); catalogued as COSV55655747, COSV99742785; called by muse, mutect2, varscan2
- TKTL2 | c.807A>T p.E269D | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.8); PolyPhen benign (0.009); catalogued as COSV99761493; called by muse, mutect2, varscan2
- TMPRSS11B | c.687G>A p.K229= | Splice Region (SNP) | VAF 7/27 reads (26%) | catalogued as COSV60291749; called by muse, mutect2, varscan2
- TNNI1 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs562023279, COSV100270331; called by muse, mutect2, varscan2
- TNR | c.2820G>T p.E940D | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV99690186; called by muse, mutect2, varscan2
- TNS2 | c.2705C>T p.S902L (on ENST00000314250 / NM_170754.4; = p.S912L on NM_015319.2) | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100036773; called by muse, mutect2, varscan2
- TNXB | c.8417G>A p.R2806K (on ENST00000647633; = p.R2559K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (1); PolyPhen possibly damaging (0.511); catalogued as COSV100926418; called by muse, mutect2, varscan2
- TREML4 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 122/231 reads (53%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.702); catalogued as COSV58385561; called by muse, mutect2, varscan2
- TRHDE | c.2534G>A p.R845K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as rs1018592817, COSV99671313; called by muse, mutect2, varscan2
- TRIB3 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.37); PolyPhen benign (0.062); catalogued as COSV99423844; called by muse, mutect2, varscan2
- TRIM15 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.68); catalogued as rs765539268, COSV64989061; called by muse, mutect2, varscan2
- TRMT13 | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as rs950891502, COSV61583189, COSV99048576; called by muse, mutect2, varscan2
- TRPV5 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 45/99 reads (45%) | catalogued as rs141452078, COSV99520344; called by muse, mutect2, varscan2
- TSSK1B | c.929C>T p.T310I | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.069); catalogued as COSV101181108; called by muse, mutect2, varscan2
- TTLL13P | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100296592; called by muse, mutect2, varscan2
- TTN | c.81982G>A p.D27328N (on ENST00000591111; = p.D19904N on NM_003319.4) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | PolyPhen probably damaging (0.996); catalogued as COSV100618255; called by muse, mutect2, varscan2
- TTN | c.20401G>A p.A6801T (on ENST00000591111; = p.A5874T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | PolyPhen probably damaging (0.998); catalogued as COSV100618259; called by muse, mutect2, varscan2
- TTN | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100618262; called by muse, mutect2, varscan2
- U2SURP | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.446); catalogued as rs1481422435, COSV67530658; called by muse, mutect2
- UBXN10 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as rs558499361, COSV66771838; called by muse, mutect2, varscan2
- UNC13C | c.3841C>T p.R1281* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as COSV52907064; called by muse, mutect2
- USP37 | c.1675C>T p.L559F | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99294561; called by muse, mutect2, varscan2
- VN1R4 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as rs1297104617, COSV100237455; called by muse, mutect2, varscan2
- VOPP1 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs757612089, COSV99567117; called by muse, mutect2, varscan2
- VPS13D | c.6286G>A p.E2096K | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV50637394, COSV99167263; called by muse, mutect2, varscan2
- VWA8 | c.1600C>T p.R534* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as rs1180405587, COSV99864412; called by muse, mutect2, varscan2
- VWF | c.7363G>A p.D2455N | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.9); catalogued as rs763541335, COSV99779035; called by muse, mutect2, varscan2
- YTHDC1 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs763860504, COSV60011193; called by muse, mutect2, varscan2
- ZACN | c.339G>C p.E113D | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100135405; called by muse, mutect2, varscan2
- ZBBX | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100283839, COSV56786622; called by muse, mutect2, varscan2
- ZBED4 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs1316600157, COSV53465594; called by muse, mutect2, varscan2
- ZDBF2 | c.2965C>T p.Q989* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100985048; called by muse, mutect2, varscan2
- ZDBF2 | c.6761C>T p.S2254F | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as COSV100985049; called by muse, mutect2
- ZEB2 | c.2239C>G p.L747V | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.396); catalogued as COSV100356323, COSV57957016; called by muse, mutect2, varscan2
- ZMYM4 | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs868319946, COSV58907785; called by muse, varscan2
- ZNF175 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV51797919; called by muse, mutect2, varscan2
- ZNF208 | c.3157G>A p.G1053R | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.594); catalogued as COSV101237068; called by muse, mutect2, varscan2
- ZNF229 | c.347T>C p.L116S | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV99350539; called by muse, mutect2, varscan2
- ZNF266 | c.1479A>T p.K493N | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV100749408; called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as COSV100606178; called by muse, mutect2, varscan2
- ZNF672 | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs1241832475, COSV100129250; called by muse, mutect2
- ZNF675 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 56/111 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV63095204; called by muse, mutect2, varscan2
- ZNF676 | c.599C>T p.S200F (on ENST00000650058; = p.S168F on NM_001001411.3) | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV68093188; called by muse, mutect2, varscan2
- ZNF777 | c.2245C>T p.P749S | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99925170; called by muse, mutect2, varscan2
- ZNF793 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.775); catalogued as COSV101495676; called by muse, mutect2, varscan2
- ZNF99 | c.2410C>G p.L804V | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101233865, COSV68057026; called by muse, mutect2, varscan2
- FLNC | c.2748_2749delinsA p.D917Tfs*5 | Frame Shift Del (DEL) | VAF 27/115 reads (23%) | called by pindel, varscan2*
- IGKV2-24 | c.5G>C p.R2T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PODN | c.1758del p.A587Pfs*33 (on ENST00000395871; = p.A539Pfs*33 on NM_153703.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 24/49 reads (49%) | called by mutect2, pindel, varscan2
- TTC17 | c.2512-9_2520del p.X838_splice | Splice Site (DEL) | VAF 20/70 reads (29%) | called by mutect2, pindel, varscan2
- ABCA8 | c.4050G>A p.R1350= | Silent (SNP) | VAF 61/319 reads (19%) | catalogued as COSV52196810; called by muse, mutect2, varscan2
- ABCC1 | c.2034C>T p.G678= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV100579820; called by muse, mutect2, varscan2
- ABCC10 | c.4021C>T p.L1341= (on ENST00000372530 / NM_001198934.2; = p.L1313= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/78 reads (67%) | catalogued as COSV99767434; called by muse, mutect2, varscan2
- ADAM23 | c.756C>T p.T252= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV100007997; called by muse, mutect2, varscan2
- ADAMTS15 | c.1791C>T p.L597= | Silent (SNP) | VAF 54/118 reads (46%) | catalogued as COSV100143128; called by muse, mutect2, varscan2
- ADCY8 | c.1014C>T p.I338= | Silent (SNP) | VAF 63/246 reads (26%) | catalogued as COSV53904799, COSV99652808; called by muse, mutect2, varscan2
- AGAP2 | c.1254G>A p.G418= (on ENST00000547588 / NM_001122772.2; = p.G82= on NM_014770.4) | Silent (SNP) | VAF 55/146 reads (38%) | catalogued as COSV99223539; called by muse, mutect2, varscan2
- AHCTF1 | c.6387C>T p.S2129= (on ENST00000366508; = p.S2103= on NM_015446.5) | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as COSV100403941; called by muse, mutect2, varscan2
- AHDC1 | c.4089C>T p.F1363= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV99899449; called by muse, mutect2, varscan2
- AIMP2 | c.198G>C p.L66= | Silent (SNP) | VAF 66/166 reads (40%) | catalogued as COSV99774042; called by muse, mutect2, varscan2
- AIPL1 | c.927G>A p.E309= | Silent (SNP) | VAF 26/32 reads (81%) | catalogued as COSV100006097; called by muse, mutect2, varscan2
- ANGPT1 | c.1464C>T p.S488= | Silent (SNP) | VAF 86/145 reads (59%) | catalogued as rs768471931, COSV99863226, COSV99864158; called by muse, mutect2, varscan2
- AQP4 | c.711C>T p.P237= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV101270472; called by muse, mutect2, varscan2
- ARFIP2 | c.204C>T p.G68= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs1564984682, COSV54446521; called by muse, mutect2, varscan2
- ARMC5 | c.2175C>T p.P725= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99192598; called by muse, mutect2, varscan2
- ASAH2 | c.837G>A p.K279= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs1215045936; called by muse, mutect2, varscan2
- ATP8B3 | c.3684C>T p.P1228= | Silent (SNP) | VAF 13/18 reads (72%) | catalogued as COSV100034544; called by muse, mutect2, varscan2
- BPIFA3 | c.729A>G p.Q243= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as COSV100967067; called by muse, varscan2
- C10orf71 | c.297C>T p.F99= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as COSV100110295; called by muse, mutect2, varscan2
- C6 | c.2058C>T p.C686= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV99667315; called by muse, mutect2, varscan2
- CAMK4 | c.255C>T p.I85= | Silent (SNP) | VAF 35/65 reads (54%) | catalogued as rs201866448, COSV56662707; called by muse, mutect2, varscan2
- CAPN9 | c.27G>A p.G9= | Silent (SNP) | VAF 35/116 reads (30%) | catalogued as rs777388741, COSV99680599; called by muse, mutect2, varscan2
- CD2BP2 | c.585C>T p.S195= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV99977134; called by muse, mutect2, varscan2
- CDH18 | c.1662G>A p.R554= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as rs970497849, COSV56912298; called by muse, mutect2, varscan2
- CEACAM5 | c.327C>T p.I109= | Silent (SNP) | VAF 80/163 reads (49%) | catalogued as COSV55751504; called by muse, mutect2
- CIP2A | c.282G>A p.Q94= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99842983; called by muse, mutect2, varscan2
- CLCNKA | c.471C>G p.T157= | Silent (SNP) | VAF 41/97 reads (42%) | catalogued as rs201270640, COSV100510170; called by muse, mutect2, varscan2
- CLEC14A | c.1302G>A p.R434= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs758464635, COSV100643614; called by muse, mutect2, varscan2
- CNTN5 | c.678C>T p.I226= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV54286454; called by muse, mutect2, varscan2
- COL17A1 | c.2439G>A p.G813= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs774874798, COSV100793207; called by muse, mutect2, varscan2
- COL8A1 | c.600G>A p.G200= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as rs759068904, COSV99657985; called by muse, mutect2, varscan2
- CPNE2 | c.675C>T p.P225= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV99321456; called by muse, mutect2, varscan2
- CRIP3 | c.336C>T p.P112= | Silent (SNP) | VAF 15/22 reads (68%) | catalogued as COSV99240403; called by muse, mutect2, varscan2
- CSMD1 | c.4833G>A p.G1611= (on ENST00000520002; = p.G1610= on NM_033225.6) | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as rs1396669871, COSV100149726; called by muse, mutect2, varscan2
- CYP11B1 | c.84C>T p.A28= | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as rs906336753, COSV52830619; called by muse, mutect2, varscan2
- CYP4F11 | c.672C>T p.A224= | Silent (SNP) | VAF 68/118 reads (58%) | catalogued as rs1314182907, COSV56130599; called by muse, mutect2, varscan2
- CYP4F2 | c.1413G>A p.Q471= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV99686090; called by muse, mutect2, varscan2
- CYP4F3 | c.1413G>A p.Q471= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV99658304; called by mutect2, varscan2
- DACH1 | c.1041C>T p.I347= | Silent (SNP) | VAF 53/123 reads (43%) | catalogued as rs1302518780, COSV100498603, COSV57488898; called by muse, mutect2, varscan2
- DENND4B | c.4233C>T p.L1411= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV63409015; called by muse, mutect2, varscan2
- DENND5B | c.3747C>T p.S1249= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as rs1452902656, COSV100171644; called by muse, mutect2, varscan2
- DHX30 | c.3261C>T p.F1087= (on ENST00000445061 / NM_138615.3; = p.F1048= on NM_014966.3) | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as rs555249138, COSV99275641; called by muse, mutect2, varscan2
- DNAH17 | c.6837C>T p.I2279= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as rs761949105, COSV67755094; called by muse, mutect2, varscan2
- DNAH8 | c.11409C>T p.I3803= | Silent (SNP) | VAF 33/134 reads (25%) | catalogued as COSV100545937; called by muse, mutect2, varscan2
- DOCK3 | c.1698C>A p.P566= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV99812986; called by muse, mutect2, varscan2
- DOCK6 | c.3093C>T p.S1031= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV99625875; called by muse, mutect2, varscan2
- DPP8 | c.2283C>T p.S761= (on ENST00000341861 / NM_001320875.2; = p.S745= on NM_130434.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as COSV100202438; called by muse, mutect2, varscan2
- DSC1 | c.996C>T p.F332= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs371108741, COSV57146138; called by muse, mutect2, varscan2
- DTX2 | c.171G>A p.G57= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs760370340, COSV100184670; called by muse, mutect2, varscan2
- EDEM2 | c.252C>T p.T84= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV100993794; called by muse, mutect2, varscan2
- EI24 | c.363C>T p.F121= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as rs769113421, COSV99629113; called by muse, mutect2, varscan2
- EIF4G1 | c.2145C>T p.I715= (on ENST00000346169 / NM_198241.3; = p.I520= on NM_004953.5) | Silent (SNP) | VAF 58/139 reads (42%) | catalogued as COSV59993279; called by muse, mutect2, varscan2
- ENPEP | c.432C>T p.L144= | Silent (SNP) | VAF 56/149 reads (38%) | catalogued as COSV54446970; called by muse, mutect2, varscan2
- FABP12 | c.222C>T p.I74= | Silent (SNP) | VAF 43/162 reads (27%) | catalogued as COSV64617856; called by muse, mutect2, varscan2
- FAM170A | c.111C>T p.S37= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV58924810; called by muse, mutect2, varscan2
- FILIP1 | c.2475G>A p.R825= | Silent (SNP) | VAF 54/65 reads (83%) | catalogued as rs267601126, COSV52723493; called by muse, mutect2, varscan2
- FLG | c.5241C>T p.H1747= | Silent (SNP) | VAF 90/340 reads (26%) | catalogued as rs1334880353, COSV100911682, COSV64243379; called by muse, varscan2
- FUT5 | c.234C>T p.I78= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV53138150; called by muse, mutect2, varscan2
- GABRR3 | c.490C>T p.L164= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV101512302; called by muse, mutect2, varscan2
- GANC | c.2106C>T p.F702= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as COSV100530998; called by muse, mutect2, varscan2
- GBA3 | c.741C>T p.I247= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as COSV101545529; called by muse, mutect2, varscan2
- GFRAL | c.846C>T p.I282= | Silent (SNP) | VAF 43/99 reads (43%) | catalogued as COSV100475366; called by muse, mutect2, varscan2
- GK2 | c.84C>T p.F28= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV100725981; called by muse, mutect2, varscan2
- GPR39 | c.141G>A p.G47= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV100257141; called by muse, mutect2, varscan2
- GRAMD1C | c.250C>T p.L84= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV100822923; called by muse, mutect2, varscan2
- HCN1 | c.2475G>A p.T825= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV57532440, COSV57534071; called by muse, mutect2, varscan2
- HCN1 | c.573C>T p.I191= | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as COSV57536693; called by muse, mutect2, varscan2
- HECW1 | c.3981C>T p.I1327= | Silent (SNP) | VAF 77/189 reads (41%) | catalogued as COSV101223872; called by muse, mutect2, varscan2
- HMCN1 | c.5064C>T p.I1688= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs952090412, COSV99630903; called by muse, mutect2, varscan2
- HNF1A | c.1749G>A p.R583= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1458498668, COSV99982683; called by muse, mutect2, varscan2
- HRC | c.1656G>A p.R552= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99418046; called by muse, mutect2
- IFNA8 | c.60C>T p.S20= | Silent (SNP) | VAF 63/71 reads (89%) | catalogued as COSV101206912; called by muse, mutect2, varscan2
- IGKV1-9 | c.291C>T p.I97= | Silent (SNP) | VAF 33/139 reads (24%) | called by muse, mutect2, varscan2
- IL16 | c.3763C>T p.L1255= (on ENST00000302987 / NM_172217.5; = p.L554= on NM_004513.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/108 reads (33%) | catalogued as COSV100250862; called by muse, mutect2, varscan2
- IL1RL2 | c.915G>A p.V305= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99960785; called by muse, mutect2, varscan2
- IL4R | c.1677C>T p.L559= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as rs766083512, COSV99405120; called by muse, mutect2, varscan2
- INA | c.15G>A p.S5= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs377641394; called by muse, mutect2, varscan2
- INPP5A | c.882C>T p.F294= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV61247229; called by muse, mutect2, varscan2
- INSL4 | c.396A>T p.G132= | Silent (SNP) | VAF 33/41 reads (80%) | catalogued as COSV99497157, COSV99497267; called by muse, mutect2, varscan2
- INSR | c.234C>T p.F78= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as COSV57158508, COSV57173109; called by muse, mutect2, varscan2
- INTS1 | c.6546G>A p.R2182= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as rs1272196679, COSV101248029; called by muse, mutect2, varscan2
- INTS3 | c.2289C>T p.I763= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs549092691, COSV100015837; called by muse, mutect2, varscan2
- IQGAP2 | c.357G>A p.A119= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as rs746302129, COSV99167516; called by muse, mutect2, varscan2
- JMJD4 | c.15G>A p.P5= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as COSV100248271; called by muse, mutect2, varscan2
- KCNG1 | c.135G>A p.R45= | Silent (SNP) | VAF 24/37 reads (65%) | catalogued as COSV100857116; called by muse, mutect2, varscan2
- KEL | c.207C>T p.F69= | Silent (SNP) | VAF 39/75 reads (52%) | catalogued as COSV100787139; called by muse, varscan2
- KIAA1217 | c.4956T>C p.I1652= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV100286811; called by muse, mutect2, varscan2
- KIAA1549 | c.2760C>T p.S920= | Silent (SNP) | VAF 37/53 reads (70%) | catalogued as rs756922238, COSV99651103; called by muse, mutect2, varscan2
- KRT82 | c.210G>A p.R70= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs139979674; called by muse, mutect2, varscan2
- L1TD1 | c.1071C>T p.F357= | Silent (SNP) | VAF 38/79 reads (48%) | catalogued as rs1205062107, COSV63133123; called by muse, mutect2, varscan2
- LARP1B | c.2232C>T p.F744= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99218489; called by muse, mutect2, varscan2
- LCT | c.3360C>T p.I1120= | Silent (SNP) | VAF 32/61 reads (52%) | catalogued as COSV99929747; called by muse, mutect2, varscan2
- LGALS9C | c.279C>T p.F93= | Silent (SNP) | VAF 27/35 reads (77%) | catalogued as COSV60195911; called by muse, mutect2, varscan2
- LIMK1 | c.852G>A p.A284= | Silent (SNP) | VAF 59/264 reads (22%) | catalogued as rs782624570, COSV100283245; called by muse, mutect2, varscan2
- LPAR4 | c.459G>A p.R153= | Silent (SNP) | VAF 41/45 reads (91%) | catalogued as COSV70913671; called by muse, mutect2, varscan2
- LRG1 | c.519G>A p.G173= | Silent (SNP) | VAF 62/162 reads (38%) | catalogued as COSV100014854, COSV56704286; called by muse, mutect2, varscan2
- LRP4 | c.1791C>T p.L597= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as rs1392302763, COSV101066682; called by muse, mutect2, varscan2
- LRRC15 | c.219C>T p.F73= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV100752776; called by muse, mutect2, varscan2
- LTBP4 | c.3342C>T p.F1114= (on ENST00000308370 / NM_001042544.1; = p.F1077= on NM_003573.2) | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV99195552; called by muse, mutect2, varscan2
- MAOA | c.687G>A p.R229= | Silent (SNP) | VAF 42/47 reads (89%) | catalogued as COSV100108817; called by muse, mutect2, varscan2
- MAPK13 | c.801G>A p.R267= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as rs140263594; called by muse, mutect2, varscan2
- MED24 | c.2769C>T p.F923= | Silent (SNP) | VAF 9/10 reads (90%) | catalogued as rs1056343446, COSV99842462; called by muse, mutect2
- MERTK | c.735C>T p.S245= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV54929162; called by muse, mutect2, varscan2
- MICAL2 | c.4659G>A p.G1553= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs746073389, COSV99811933; called by muse, mutect2, varscan2
- MORC1 | c.492T>C p.F164= | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as COSV51717370, COSV99226614; called by muse, mutect2, varscan2
- NFRKB | c.75C>T p.I25= (on ENST00000446488 / NM_001143835.2; = p.I38= on NM_006165.3) | Silent (SNP) | VAF 36/81 reads (44%) | catalogued as COSV100451967; called by muse, mutect2, varscan2
- NFYB | c.339C>T p.I113= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV99527210; called by muse, mutect2, varscan2
- NOC2L | c.984C>T p.F328= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs113292586, COSV100498064; called by muse, mutect2, varscan2
- NPAP1 | c.369C>T p.F123= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as COSV100275579, COSV61508156; called by muse, mutect2, varscan2
- NPSR1 | c.981C>T p.P327= | Silent (SNP) | VAF 43/208 reads (21%) | catalogued as COSV62200781; called by muse, mutect2, varscan2
- NRK | c.1161G>A p.G387= | Silent (SNP) | VAF 33/42 reads (79%) | catalogued as COSV99688224; called by muse, mutect2, varscan2
- NWD1 | c.4440C>T p.I1480= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV100342957; called by muse, mutect2, varscan2
- OR10R2 | c.96C>T p.F32= | Silent (SNP) | VAF 65/208 reads (31%) | catalogued as COSV63769445, COSV63769564; called by muse, mutect2, varscan2
- OR11G2 | c.192C>T p.L64= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV100639980; called by muse, mutect2, varscan2
- OR1L4 | c.279C>T p.I93= | Silent (SNP) | VAF 56/63 reads (89%) | catalogued as COSV99413902; called by muse, mutect2, varscan2
- OR2AT4 | c.486C>T p.I162= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs771314400, COSV100532362; called by muse, mutect2, varscan2
- OR2T33 | c.699G>A p.K233= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as rs767623642, COSV58818100, COSV58818310; called by muse, mutect2
- OR2T33 | c.135C>T p.L45= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as COSV100532025; called by muse, mutect2, varscan2
- OR4Q3 | c.687C>T p.I229= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV59177386; called by muse, mutect2
- OR52N2 | c.267C>T p.F89= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as COSV57677868, COSV57677877; called by muse, mutect2
- OR6Y1 | c.108C>T p.F36= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs775578919, COSV56928746; called by muse, mutect2, varscan2
- OR7D2 | c.678G>A p.R226= | Silent (SNP) | VAF 49/94 reads (52%) | catalogued as COSV100712928; called by muse, mutect2, varscan2
- OR8K1 | c.585T>C p.C195= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as COSV99687387; called by muse, mutect2, varscan2
- OTOF | c.3207C>T p.F1069= (on ENST00000272371 / NM_194248.3; = p.F322= on NM_004802.4) | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs267599306, COSV99718061; called by muse, mutect2, varscan2
- OTOF | c.1692C>T p.S564= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV55503950; called by muse, mutect2, varscan2
- P3H2 | c.525C>T p.F175= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as rs567532723, COSV60027706; called by muse, mutect2, varscan2
- PAPPA2 | c.3106C>T p.L1036= | Silent (SNP) | VAF 34/131 reads (26%) | catalogued as COSV100868309; called by muse, mutect2, varscan2
- PCDHA10 | c.315G>A p.L105= | Silent (SNP) | VAF 92/106 reads (87%) | catalogued as COSV100251513; called by muse, mutect2, varscan2
- PCDHA4 | c.1107C>T p.I369= | Silent (SNP) | VAF 33/70 reads (47%) | catalogued as rs942791264, COSV63546137; called by muse, mutect2, varscan2
- PCDHB13 | c.2124C>T p.F708= | Silent (SNP) | VAF 68/179 reads (38%) | catalogued as COSV53394669; called by muse, mutect2, varscan2
- PCNX4 | c.2418C>T p.S806= (on ENST00000406854 / NM_001330177.2; = p.S572= on NM_022495.5) | Silent (SNP) | VAF 47/122 reads (39%) | catalogued as rs769562556, COSV100470487; called by muse, mutect2, varscan2
- PDPR | c.600C>T p.S200= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as COSV99848467; called by muse, mutect2, varscan2
- PEAR1 | c.2739G>A p.G913= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV52775236; called by muse, mutect2, varscan2
- PGS1 | c.1572G>A p.L524= | Silent (SNP) | VAF 29/237 reads (12%) | catalogued as rs754583865, COSV99428318; called by muse, mutect2, varscan2
- PI4KB | c.1284C>T p.S428= (on ENST00000368873 / NM_001369623.1; = p.S440= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as rs369304753; called by muse, mutect2, varscan2
- PKD1L1 | c.1848C>T p.F616= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as rs747620748, COSV56961626; called by muse, mutect2, varscan2
- PLXNA2 | c.2127G>A p.E709= | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as COSV100885588; called by muse, mutect2, varscan2
- PNPLA7 | c.3525C>T p.I1175= | Silent (SNP) | VAF 28/33 reads (85%) | catalogued as COSV99480958; called by muse, mutect2, varscan2
- PPP3CB | c.96C>T p.F32= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV100646185, COSV61152089; called by muse, mutect2, varscan2
- PSMD4 | c.1074C>T p.S358= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as COSV100924674; called by muse, mutect2, varscan2
- PTPRU | c.2874C>T p.F958= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as COSV100113056; called by muse, mutect2, varscan2
- RAP1GAP2 | c.342C>T p.I114= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs779978689, COSV54592492, COSV99624717; called by muse, mutect2, varscan2
- RAPGEF5 | c.909C>T p.I303= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs1054834177, COSV59784394; called by muse, mutect2, varscan2
- RORB | c.615C>T p.T205= (on ENST00000396204 / NM_001365023.1; = p.T194= on NM_006914.4) | Silent (SNP) | VAF 26/30 reads (87%) | catalogued as COSV65338921; called by muse, mutect2, varscan2
- RYR1 | c.4656C>T p.F1552= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs1401779403, COSV100616091, COSV100617396; called by muse, mutect2, varscan2
- SCARA3 | c.1572A>G p.S524= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100106886; called by muse, mutect2
- SCN1A | c.4911G>A p.V1637= (on ENST00000303395 / NM_001202435.3; = p.V1626= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/77 reads (53%) | catalogued as COSV100320881; called by muse, mutect2, varscan2
- SDK2 | c.3117G>A p.E1039= | Silent (SNP) | VAF 40/194 reads (21%) | catalogued as rs147287702, COSV101167833; called by muse, mutect2, varscan2
- SEMA3D | c.1743C>T p.I581= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as COSV99406864; called by muse, mutect2, varscan2
- SIGLEC12 | c.1491C>T p.I497= (on ENST00000291707 / NM_053003.4; = p.I379= on NM_033329.2) | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV99389421; called by muse, mutect2
- SLC17A8 | c.447C>T p.F149= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV60123397, COSV60126191; called by muse, mutect2, varscan2
- SLC25A21 | c.229C>T p.L77= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as COSV100491508; called by muse, mutect2, varscan2
- SLC27A6 | c.354C>T p.F118= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs1372634243, COSV52479372; called by muse, mutect2, varscan2
- SLC2A2 | c.1251G>A p.P417= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs371657103; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC6A20 | c.1347G>A p.T449= | Silent (SNP) | VAF 37/107 reads (35%) | catalogued as rs750000267, COSV100653772; called by muse, mutect2, varscan2
- SLN | c.72C>T p.L24= | Silent (SNP) | VAF 44/85 reads (52%) | catalogued as rs939920966, COSV100019491; called by muse, mutect2, varscan2
- SMURF1 | c.2187C>T p.I729= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as rs537408968, COSV100705438; called by muse, mutect2, varscan2
- SORL1 | c.6225G>A p.G2075= | Silent (SNP) | VAF 46/87 reads (53%) | catalogued as COSV52758256, COSV99494287; called by muse, mutect2, varscan2
- SPHK1 | c.996G>A p.K332= (on ENST00000392496 / NM_001355139.2; = p.K346= on NM_021972.4) | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as COSV100039416; called by muse, mutect2, varscan2
- SPINK7 | c.174C>T p.I58= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as COSV99199133; called by muse, mutect2, varscan2
- SPTBN4 | c.5385C>T p.I1795= | Silent (SNP) | VAF 19/29 reads (66%) | catalogued as rs200956251; called by muse, mutect2, varscan2
- SRD5A2 | c.582C>T p.F194= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as CM995320, COSV51870965; called by mutect2, varscan2
- STAB2 | c.1170C>T p.L390= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV101186071; called by muse, mutect2, varscan2
- STAB2 | c.1171C>T p.L391= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV101186073; called by muse, mutect2, varscan2
- SYNPO2 | c.3498G>A p.R1166= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as rs193107244; called by muse, mutect2, varscan2
- TAF5L | c.1189C>T p.L397= | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as COSV99273373; called by muse, mutect2, varscan2
- TBX5 | c.201C>T p.F67= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs752768742, COSV100091452; called by muse, mutect2, varscan2
- TCEA3 | c.657C>T p.I219= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs1020258736, COSV71531948; called by muse, mutect2, varscan2
- TCHHL1 | c.27C>T p.L9= | Silent (SNP) | VAF 26/119 reads (22%) | catalogued as COSV100916555, COSV64286122; called by muse, mutect2, varscan2
- THAP10 | c.465C>T p.P155= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs1163865180, COSV51436632, COSV99997817; called by muse, mutect2, varscan2
- TLR8 | c.222C>T p.F74= (on ENST00000218032 / NM_138636.5; = p.F92= on NM_016610.4) | Silent (SNP) | VAF 58/63 reads (92%) | catalogued as COSV99487102; called by muse, mutect2, varscan2
- TNFRSF11A | c.1542C>T p.S514= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV99500310; called by muse, mutect2, varscan2
- TNR | c.321C>T p.D107= | Silent (SNP) | VAF 40/111 reads (36%) | catalogued as COSV99690187; called by muse, mutect2, varscan2
- TNRC6C | c.3915C>T p.S1305= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV100050147; called by muse, mutect2, varscan2
- TNXB | c.12261C>T p.F4087= (on ENST00000647633; = p.F3840= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 64/206 reads (31%) | catalogued as rs747001277, COSV100926417; called by muse, mutect2, varscan2
- TPTE | c.1131C>T p.T377= (on ENST00000618007 / NM_199261.4; = p.T359= on NM_199259.4) | Silent (SNP) | VAF 19/135 reads (14%) | catalogued as rs1468534951; called by muse, mutect2, varscan2
- TRANK1 | c.6138C>T p.I2046= | Silent (SNP) | VAF 19/24 reads (79%) | catalogued as COSV100083440; called by muse, mutect2, varscan2
- TRIM50 | c.1329G>A p.Q443= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1554543239; called by muse, mutect2
- TUBA8 | c.699G>A p.Q233= | Silent (SNP) | VAF 42/105 reads (40%) | catalogued as COSV100283150; called by muse, mutect2, varscan2
- UBR4 | c.3072C>T p.S1024= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100921150; called by muse, mutect2, varscan2
- UNC5A | c.1335G>A p.G445= | Silent (SNP) | VAF 40/86 reads (47%) | catalogued as COSV99994718; called by muse, mutect2, varscan2
- USP5 | c.1284C>T p.F428= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as rs782698490, COSV99978744; called by muse, mutect2, varscan2
- VWA5A | c.690C>T p.L230= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV100795679, COSV63707174; called by muse, mutect2, varscan2
- VWF | c.2727G>A p.V909= | Silent (SNP) | VAF 35/78 reads (45%) | catalogued as rs763257958, COSV99779400; called by muse, mutect2, varscan2
- WDFY3 | c.723C>T p.T241= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV55708406; called by muse, mutect2, varscan2
- XPO7 | c.693C>T p.F231= | Silent (SNP) | VAF 41/160 reads (26%) | catalogued as COSV99381521; called by muse, mutect2, varscan2
- ZFC3H1 | c.5043C>T p.I1681= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV101110600; called by muse, mutect2, varscan2
- ZIC1 | c.1125T>C p.S375= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as rs957903094, COSV99292070; called by muse, mutect2, varscan2
- ZMIZ2 | c.1284C>A p.R428= | Silent (SNP) | VAF 44/86 reads (51%) | catalogued as COSV99536977; called by muse, mutect2, varscan2
- ZNF17 | c.1938C>T p.V646= | Silent (SNP) | VAF 28/50 reads (56%) | catalogued as COSV100300078; called by muse, mutect2, varscan2
- ZNF222 | c.351C>T p.F117= | Silent (SNP) | VAF 30/53 reads (57%) | catalogued as COSV99496420; called by muse, mutect2, varscan2
- ZNF366 | c.237G>A p.R79= | Silent (SNP) | VAF 56/176 reads (32%) | catalogued as COSV100574319; called by muse, mutect2, varscan2
- ZNF644 | c.3579C>T p.I1193= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as COSV61346590, COSV61349541; called by muse, mutect2, varscan2
- ZNF648 | c.1032C>T p.F344= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs750530044, COSV100374474; called by muse, mutect2
- ZNF695 | c.39C>T p.F13= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV100377561; called by muse, mutect2, varscan2
- AL109984.1 | n.186+1577G>A | Intron (SNP) | VAF 20/81 reads (25%) | catalogued as COSV63752863; called by muse, mutect2, varscan2
- AL136982.4 | n.1120G>T | RNA (SNP) | VAF 89/192 reads (46%) | called by muse, mutect2, varscan2
- CCNQP1 | n.267G>A | RNA (SNP) | VAF 33/130 reads (25%) | called by muse, mutect2, varscan2
- COG5 | c.-35C>T | 5'UTR (SNP) | VAF 11/36 reads (31%) | catalogued as rs754304130, COSV51744719, COSV99709095; called by muse, mutect2, varscan2
- DCHS2 | n.3431G>A | RNA (SNP) | VAF 56/116 reads (48%) | catalogued as rs1561039077, COSV59737206; called by muse, mutect2, varscan2
- EPS8L1 | c.429+244G>A | Intron (SNP) | VAF 11/20 reads (55%) | catalogued as rs753438492, COSV99136575; called by muse, mutect2, varscan2
- MIR524 | n.48G>A | RNA (SNP) | VAF 28/100 reads (28%) | catalogued as rs1163023757; called by muse, mutect2, varscan2
- MUCL3 | c.947-41G>A | Intron (SNP) | VAF 66/97 reads (68%) | catalogued as COSV100424208; called by muse, mutect2, varscan2
- OSGIN1 | n.1544C>T | RNA (SNP) | VAF 29/64 reads (45%) | catalogued as COSV100534015; called by muse, mutect2, varscan2
- RCL1 | c.971+747A>G | Intron (SNP) | VAF 115/142 reads (81%) | catalogued as rs1003204564, COSV100762133, COSV63004591; called by muse, mutect2, varscan2
- SNORD114-17 | n.21G>A | RNA (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- SNORD116-17 | n.2G>A | RNA (SNP) | VAF 76/196 reads (39%) | called by muse, mutect2, varscan2
- TTN | c.10360+1604G>A | Intron (SNP) | VAF 18/65 reads (28%) | catalogued as COSV60022320; called by muse, mutect2, varscan2
- ZNF99 | c.*206T>A | 3'UTR (SNP) | VAF 28/74 reads (38%) | catalogued as COSV101233864; called by muse, mutect2
- ZPLD1 | c.-148T>A | 5'UTR (SNP) | VAF 32/60 reads (53%) | catalogued as COSV100083316; called by muse, mutect2, varscan2
